EXCEPTIONAL_RESPONDERS case ER-ADRU — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8583e6fc-b1d2-4a17-8b8c-4f6e831acd71

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1940; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,714 days); Year of diagnosis: 2008; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Days to last follow up: 2,905 days (8.0 years); Days to best overall response: 785 days (2.1 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 736 days (2.0 years); Days to treatment end: 1,107 days (3.0 years).
   Treatment given: Therapeutic agents: Paclitaxel; Days to treatment start: 736 days (2.0 years); Days to treatment end: 953 days (2.6 years).
   Treatment given: Therapeutic agents: Pemetrexed; Days to treatment start: 736 days (2.0 years); Days to treatment end: 995 days (2.7 years).

Follow-up (1 entry)
- Days to follow up: 2,905 days (8.0 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 720 days (2.0 years); Days progression-free: 2,905 days (8.0 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ADRU-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ADRU-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ADRU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ADRU-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 30; Percent normal cells: 5; Percent necrosis: 15; Percent stromal cells: 55; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 10.
